Somatic mutation profile of tumor specimen 5d27516f-58d7-4155-80b4-4c7f39 (aliquot 5d27516f-58d7-4155-80b4-4c7f39_D6_1) from CPTAC case 11BR073, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 64.5 years (23,572 days).
Specimen 5d27516f-58d7-4155-80b4-4c7f39: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57767b1f-f411-40e6-9342-ac4464fdb211.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ba46cb26-65c0-4c5d-95de-ef7d41 (Blood Derived Normal), aliquot ba46cb26-65c0-4c5d-95de-ef7d41_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd2e9aa7-cb14-4a40-af55-33e0e485cdac

The open-access MAF lists 95 somatic variants for this specimen: 66 protein-altering or splice-affecting, 20 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 20, RNA 4, Nonsense Mutation 3, Intron 3, Frame Shift Del 2, In Frame Del 2, 3'UTR 1, Splice Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRKCG | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 106/672 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906679, CM118203; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 27/159 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.1309C>A p.Q437K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.228); catalogued as COSV101330195; called by muse, mutect2, varscan2
- ADGRB1 | c.4108G>A p.D1370N | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as rs1183016497; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2554G>A p.V852M | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540780093; called by muse, mutect2
- KIAA2013 | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1163836607; called by muse, mutect2, varscan2
- MROH1 | c.3388G>A p.V1130M | Missense Mutation (SNP) | VAF 46/1076 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs1205994103; called by muse, mutect2
- PEX6 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 107/720 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as rs1390565278; called by muse, mutect2, varscan2
- PKHD1L1 | c.4834G>A p.E1612K | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as COSV101006917; called by muse, mutect2, varscan2
- PPP1R3F | c.1526G>C p.G509A | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV50018853; called by muse, mutect2, varscan2
- PTH2R | c.526A>G p.R176G | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1182925255; called by muse, mutect2, varscan2
- RNF150 | c.1307T>A p.V436E | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); catalogued as rs781554169; called by muse, mutect2, varscan2
- SHKBP1 | c.401-8C>T | Splice Region (SNP) | VAF 13/94 reads (14%) | catalogued as rs1481444744; called by muse, mutect2, varscan2
- SLC39A11 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.122); catalogued as rs1454910916; called by muse, mutect2, varscan2
- TTLL8 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776408711; called by muse, mutect2, varscan2
- VANGL2 | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 67/562 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV63604116; called by muse, mutect2, varscan2
- WWC2 | c.3385-1G>A p.X1129_splice | Splice Site (SNP) | VAF 25/129 reads (19%) | catalogued as rs1343135120, COSV67857374; called by muse, mutect2, varscan2
- ZNF2 | c.1214C>T p.T405M (on ENST00000611147 / NM_001291605.2; = p.T392M on NM_021088.4) | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745767414, COSV54637027; called by muse, mutect2
- APOL1 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ARHGAP15 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP22 | c.1581C>A p.S527R | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CCDC153 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2
- CHSY3 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 14/259 reads (5%) | called by muse, mutect2
- COL27A1 | c.2099G>A p.G700E | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A5 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 13/410 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.319); called by muse, mutect2
- DNAH1 | c.5929A>G p.I1977V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- DNAH11 | c.2107A>T p.N703Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DNAH8 | c.11217C>G p.Y3739* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- DNAJC28 | c.451_468del p.E151_Q156del | In Frame Del (DEL) | VAF 20/121 reads (17%) | called by mutect2, pindel, varscan2
- DOCK1 | c.2116T>C p.F706L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- DSG2 | c.1067A>T p.N356I | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EGFLAM | c.2141A>C p.Q714P | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- EPHA10 | c.2546A>G p.D849G | Missense Mutation (SNP) | VAF 11/277 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO9 | c.1171T>G p.S391A | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2
- FCRL3 | c.1289C>A p.P430H | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- FEM1C | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- GALNT1 | c.242T>A p.I81N | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2
- ICAM1 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- KIF1B | c.3164G>A p.G1055D (on ENST00000377086 / NM_001365952.1; = p.G1009D on NM_015074.3) | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- KMT2D | c.13963G>T p.A4655S | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.036); called by muse, mutect2
- LINGO4 | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- LRPPRC | c.4030_4031del p.L1344Dfs*9 | Frame Shift Del (DEL) | VAF 43/280 reads (15%) | called by mutect2, pindel, varscan2
- LRRC7 | c.1579C>A p.Q527K (on ENST00000651989 / NM_001370785.2; = p.Q494K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.047); called by muse, mutect2
- MACF1 | c.10892G>T p.G3631V (on ENST00000372915; = p.G1564V on NM_012090.5) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- MTCH1 | c.1100G>T p.G367V (on ENST00000373627 / NM_001271641.1; = p.G350V on NM_014341.2) | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC5B | c.1978G>C p.D660H | Missense Mutation (SNP) | VAF 12/301 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- NMUR1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 83/563 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- OR7G1 | c.214_255del p.C72_I85del | In Frame Del (DEL) | VAF 16/176 reads (9%) | called by mutect2, pindel
- PLXNA4 | c.366C>A p.Y122* | Nonsense Mutation (SNP) | VAF 40/322 reads (12%) | called by muse, mutect2, varscan2
- PPP1R26 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- PRSS37 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, varscan2
- RCC2 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RCN1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, mutect2
- SIGLEC1 | c.4103C>G p.T1368S | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SIRT1 | c.1457T>C p.I486T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2
- TBC1D2 | c.2021_2054del p.L674Pfs*31 | Frame Shift Del (DEL) | VAF 23/185 reads (12%) | called by mutect2, pindel, varscan2
- TEX35 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TFDP1 | c.834T>G p.N278K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- TNFAIP2 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TP53BP2 | c.1480G>T p.A494S (on ENST00000343537 / NM_001031685.3; = p.A365S on NM_005426.2) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.194); called by muse, mutect2
- TRHR | c.163C>G p.H55D | Missense Mutation (SNP) | VAF 94/906 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TRIAP1 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TUBAL3 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- UGGT1 | c.4289C>T p.A1430V | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- ZIC4 | c.551C>G p.P184R | Missense Mutation (SNP) | VAF 64/596 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ZNF513 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCC8 | c.3996G>C p.S1332= | Silent (SNP) | VAF 85/656 reads (13%) | called by muse, mutect2, varscan2
- ALX4 | c.885C>T p.T295= | Silent (SNP) | VAF 69/467 reads (15%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.57A>G p.E19= | Silent (SNP) | VAF 59/1101 reads (5%) | called by muse, mutect2
- BCL2L14 | c.588A>G p.V196= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs139420279; called by muse, mutect2, varscan2
- CBFA2T2 | c.789C>T p.I263= | Silent (SNP) | VAF 90/422 reads (21%) | catalogued as rs772239813; called by muse, mutect2, varscan2
- CDKN1B | c.45G>A p.R15= | Silent (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- COL6A6 | c.483C>T p.I161= | Silent (SNP) | VAF 17/323 reads (5%) | catalogued as COSV62019545; called by muse, mutect2
- CYP2E1 | c.315G>A p.A105= | Silent (SNP) | VAF 49/370 reads (13%) | catalogued as COSV53313972; called by muse, mutect2, varscan2
- ENAM | c.1167C>T p.G389= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs770542386; called by muse, mutect2
- FCGBP | c.2838C>T p.D946= | Silent (SNP) | VAF 21/205 reads (10%) | catalogued as rs777143294; called by muse, mutect2, varscan2
- FRAS1 | c.7218G>C p.G2406= | Silent (SNP) | VAF 36/213 reads (17%) | catalogued as rs373828330; called by muse, mutect2, varscan2
- IL7R | c.1227G>C p.G409= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as COSV57408788; called by muse, mutect2, varscan2
- KCNS3 | c.33A>C p.G11= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- MET | c.2748T>G p.S916= | Silent (SNP) | VAF 43/367 reads (12%) | catalogued as rs1488322291; called by muse, mutect2, varscan2
- NPAS4 | c.1395C>A p.T465= | Silent (SNP) | VAF 28/224 reads (13%) | catalogued as COSV60651963; called by muse, mutect2, varscan2
- OR4C11 | c.451T>C p.L151= | Silent (SNP) | VAF 18/296 reads (6%) | called by muse, mutect2
- PAPPA2 | c.729T>A p.G243= | Silent (SNP) | VAF 14/422 reads (3%) | called by muse, mutect2
- PAX9 | c.933T>C p.S311= | Silent (SNP) | VAF 79/535 reads (15%) | called by muse, mutect2, varscan2
- TACC2 | c.4548G>A p.K1516= | Silent (SNP) | VAF 10/153 reads (7%) | called by muse, mutect2
- TUT1 | c.972G>A p.S324= | Silent (SNP) | VAF 38/267 reads (14%) | catalogued as rs774988350, COSV53471578; called by muse, mutect2, varscan2
- DENND2B | c.2721-578C>T | Intron (SNP) | VAF 16/174 reads (9%) | catalogued as rs1456749586; called by muse, mutect2
- FAM205BP | n.1307G>A | RNA (SNP) | VAF 57/313 reads (18%) | called by muse, mutect2, varscan2
- FCRL3 | c.*2006C>T | 3'UTR (SNP) | VAF 12/112 reads (11%) | called by mutect2, varscan2
- MIR1302-7 | n.49C>G | RNA (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- OR10V2P | n.530G>A | RNA (SNP) | VAF 41/406 reads (10%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.2657A>G | RNA (SNP) | VAF 8/118 reads (7%) | catalogued as rs1429101608; called by muse, mutect2
- SHC3 | c.1656+519A>G | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- UBALD1 | c.184-64G>C | Intron (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- WASHC2A | chr10:50067926 G>C | 5'Flank (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
